Gene-level copy-number profile of tumor specimen HCM-WCMC-0749-C34-01A from HCMI case HCM-WCMC-0749-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Bronchio-alveolar carcinoma, mucinous; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 72.6 years (26,530 days).
Specimen HCM-WCMC-0749-C34-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8da16749-1ea6-4877-9465-a5eaf6b0ec95.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0749-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/6fb16110-0315-43f2-9d04-9f823298bfa0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 94; copy number 1: 12,335; copy number 2: 43,402; copy number 3: 3,004; copy number 4: 54; copy number 6: 18.

Homozygous deletions (total copy number 0; autosomes only): 94 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:31,179,745–31,239,887, 1 gene: NKAIN1.
- chr7:7,066,964–7,067,045, 1 gene: MIR3683.
- chr9:21,638,285–25,844,585, 37 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, TUSC1, LINC01241.
- chr10:38,403,189–38,605,609, 5 genes: AL133216.2, RNU6-1118P, CICP9, AL133216.1, ABCD1P2.
- chr11:113,387,779–113,475,691, 4 genes: ANKK1, AP002840.1, DRD2, MIR4301.
- chr12:10,505,602–10,523,135, 1 gene: EIF2S3B.
- chr12:30,926,428–31,106,830, 7 genes: TSPAN11, AC008013.1, AC008013.2, DDX11-AS1, DDX11, SNORA75, AC008013.3.
- chr15:25,169,337–25,225,284, 31 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr17:63,454,993–63,548,977, 6 genes: AC005828.5, PPIAP55, ACE, AC113554.1, ACE3P, KCNH6.
- chr22:23,070,519–23,125,032, 1 gene (within-gene range 0–1): GNAZ.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:23,197,144–23,437,961, 1 gene, copy number 6 (within-gene range 4–6): TMEM241.
- chr18:23,453,287–23,586,506, 6 genes, copy number 6: RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA.
- chr18:23,689,453–24,162,211, 11 genes, copy number 6 (within-gene range 1–6): LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3.

Autosomal genes at a single copy (total copy number 1): 9,479. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
